Gene-level copy-number profile of tumor specimen TCGA-DX-A7ES-01A from TCGA case TCGA-DX-A7ES, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 50.7 years (18,528 days).
Specimen TCGA-DX-A7ES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.47e74b95-d554-4a7a-90a8-742f96d53fa1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A7ES-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e6bd411-1b6f-4c3f-89b6-0c4369e557c1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 58,710; copy number 3: 373; copy number 4: 549; copy number 5: 54; copy number 6: 10; copy number 7: 1; copy number 8: 15; copy number 9: 2; copy number 10: 1; copy number 11: 6; copy number 12: 2; copy number 16: 19; copy number 17: 8; copy number 18: 32; copy number 19: 9; copy number 21: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A7ES-01A-31D-A38Y-01): tumor purity 0.3, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 186 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:113,581,501–113,581,947, 1 gene, copy number 9: RPS27AP11.
- chr6:148,747,030–149,811,420, 29 genes, copy number 5 (within-gene range 3–5): UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1, TAB2, TAB2-AS1, AL031056.2, RN7SL234P, FABP12P1, SUMO4, ZC3H12D, AL031133.1, PPIL4, RNU7-3P, AL078581.3, GINM1, AL078581.4, AL078581.2, RPS18P9, AL078581.1, KATNA1, Y_RNA, LATS1, AL358852.1, NUP43, PCMT1, BTBD10P2, AL355312.2.
- chr9:116,838,144–116,877,264, 1 gene, copy number 9: AL157829.1.
- chr9:124,257,606–124,353,307, 1 gene, copy number 16 (within-gene range 2–16): NEK6.
- chr9:124,353,465–124,516,056, 4 genes, copy number 16: PSMB7, ADGRD2, NR5A1, AL354979.1.
- chr9:124,598,707–124,607,458, 2 genes, copy number 16: AL669818.1, RN7SL302P.
- chr12:30,926,428–31,254,445, 11 genes, copy number 5: TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1.
- chr12:38,532,895–38,909,592, 4 genes, copy number 8: AC087897.1, AC087897.2, CPNE8, CPNE8-AS1.
- chr12:40,196,744–40,570,832, 5 genes, copy number 5 (within-gene range 2–5): LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P.
- chr12:57,723,761–58,105,935, 27 genes, copy number 18 (within-gene range 2–18): AGAP2, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:58,872,149–59,130,875, 5 genes, copy number 18: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1.
- chr12:60,341,824–60,419,293, 3 genes, copy number 5: Y_RNA, AC090022.1, AC090022.2.
- chr12:61,600,067–61,600,843, 1 gene, copy number 21: DUX4L52.
- chr12:65,758,020–65,966,291, 5 genes, copy number 19 (within-gene range 2–19): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:67,424,272–67,670,919, 6 genes, copy number 11: NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1.
- chr12:67,989,445–68,234,686, 6 genes, copy number 5 (within-gene range 2–5): IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26.
- chr12:68,332,888–68,451,663, 1 gene, copy number 19 (within-gene range 2–19): LINC02384.
- chr12:68,426,331–68,487,863, 3 genes, copy number 19: AC008033.3, AC008033.1, AC008033.2.
- chr12:68,746,125–68,971,570, 9 genes, copy number 16 (within-gene range 2–16): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5.
- chr12:69,326,574–70,243,379, 21 genes, copy number 8–21 (within-gene range 2–21): AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821.
- chr12:73,115,957–73,208,317, 3 genes, copy number 6: AC090503.2, LINC02444, AC090503.1.
- chr12:73,820,315–75,390,928, 19 genes, copy number 6–21 (within-gene range 2–21): LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2.
- chr12:78,863,993–79,452,008, 2 genes, copy number 12 (within-gene range 2–12): SYT1, AC090709.1.
- chr12:96,194,375–96,269,824, 3 genes, copy number 16 (within-gene range 12–16): ELK3, AC008149.1, AC008149.2.
- chr12:107,219,764–107,864,562, 13 genes, copy number 8–21 (within-gene range 2–21): AC007649.1, SETP7, BTBD11, AC009774.1, RNA5SP371, AC007540.1, Y_RNA, PWP1, AC007622.1, PRDM4, AC007622.2, ASCL4, AC126177.3.
- chr22:46,914,092–46,916,042, 1 gene, copy number 10: TBC1D22A-AS1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
